Somatic mutation profile of tumor specimen TCGA-DJ-A3UT-01A (aliquot TCGA-DJ-A3UT-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 43.2 years (15,767 days).
Specimen TCGA-DJ-A3UT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2dc985be-5cdd-4f75-a2ce-fc1723dd9cb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UT-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UT-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f33eae6-fe58-48fb-94c2-ccfacb363dda

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 107/259 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C4A | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.981); catalogued as COSV71179103; called by muse, mutect2
- COX7B | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV63782923, COSV63783312; called by muse, mutect2, varscan2
- GRIA1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs149549228, COSV53615957; called by muse, mutect2, varscan2
- GRIA2 | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.489); catalogued as COSV52409098; called by muse, mutect2
- NT5C1A | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs755046790, COSV52493737; called by muse, mutect2
- PLEKHM2 | c.2332C>G p.L778V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65398587; called by muse, mutect2, varscan2
- THEMIS | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs759978898, COSV64074923; called by muse, mutect2
- RBMX2 | c.724C>T p.L242= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV59730128; called by muse, mutect2
- ZNF346 | c.207C>T p.L69= | Silent (SNP) | VAF 41/307 reads (13%) | catalogued as COSV56158552; called by muse, mutect2, varscan2
- VGLL4 | c.65-41457T>G | Intron (SNP) | VAF 42/277 reads (15%) | catalogued as COSV56082528; called by muse, mutect2, varscan2
